Gene-level copy-number profile of tumor specimen HTMCP-03-06-02239-01A from CGCI case HTMCP-03-06-02239, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 48.2 years (17,613 days).
Specimen HTMCP-03-06-02239-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e115e88e-3637-48d4-8ab2-10006d92960f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02239-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/e99a3b6e-b89e-4e95-9927-01e2ee042947

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 7,974; copy number 2: 41,837; copy number 3: 8,182; copy number 4: 132; copy number 5: 62; copy number 6: 23; copy number 7: 21; copy number 8: 75; copy number 10: 43; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–827,796, 25 genes (within-gene range 0–1): AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AL669831.3, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr3:64,174,401–64,200,965, 2 genes (within-gene range 0–1): PRDX3P4, PRICKLE2-AS3.
- chr4:10,238,213–10,238,235, 1 gene: AC006499.8.
- chr5:179,732,822–179,838,078, 5 genes (within-gene range 0–1): MAML1, LTC4S, MGAT4B, MIR1229, SQSTM1.
- chr19:1,177,558–1,228,431, 2 genes (within-gene range 0–1): STK11, HMGB2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 225 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:201,377,207–202,303,661, 39 genes, copy number 5: TRAK2, STRADB, SCYL2P1, Y_RNA, C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11, RNU6-440P, AC069148.1, FZD7, KIAA2012, KIAA2012-AS1, AC079354.2, AC079354.1, PSMA2P3, DAZAP2P1, SUMO1, RPL39P14, NOP58, SNORD70, SNORD70B, SNORD11B, SNORD11, AC064836.3.
- chr11:100,641,975–103,895,271, 61 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr19:42,507,304–42,561,750, 2 genes, copy number 6 (within-gene range 3–6): CEACAM1, CEACAMP2.
- chr19:42,902,086–44,821,421, 96 genes, copy number 6–10 (broad region; genes not listed).
- chr21:12,999,676–13,777,266, 27 genes, copy number 5–29: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1.

Autosomal genes at a single copy (total copy number 1): 7,974. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
